Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4972, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4972-01A (Primary Tumor).

[page 1 of 2]
Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

TCGA - BP - 4972

Clinical Diagnosis & History:

with renal mass.

Specimens Submitted:

1: SP: Kidney, left, partial nephrectomy

DIAGNOSIS:

1. SP: Kidney, left, partial nephrectomy

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:

Nuclear grade III/IV

Tumor Size:

Greatest diameter is 4.2 cm.

Local Invasion (for renal cortical types):

Extends through renal capsule but confined within Gerota's fascia

Renal Vein Invasion:

Not identified

Small vessel angiolymphatic invasion is not identified.

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Shows a benign cortical cyst; otherwise unremarkable

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT3a Tumor invades the adrenal gland or perinephric tissues but not beyond Gerota's fascia

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[page 2 of 2]
[REDACTED]

[REDACTED]

Gross Description:

[REDACTED]

1). The specimen is received fresh for frozen section consultation and is labeled "left renal tumor, stitch marks deep margin". It consists of a 5.5 x 5.3 x 3.5 cm wedge shaped portion of kidney with a suture marking the deep margin. The margin is inked black, the capsule is inked blue and the specimen is serially sectioned to reveal a yellow – orange focally hemorrhagic and cystic mass measuring 4.2 x 4.2 x 4.5 cm. The clearance from the resection margin is 0.8 cm. The tumor grossly involves the capsule, and is 1 mm from the inked capsular margin. A representative section of the nearest margin is submitted for frozen section diagnosis. Representatively submitted. Portions of the tumor are submitted for TPS.

Summary of sections:
FSC - frozen section control
T – tumor
TC-tumor with capsule
M - margin

Summary of Sections:

Part 1: SP: Kidney, left, partial nephrectomy [REDACTED]

Block	Sect. Site	PCs
1	FSC	1
2	M	2
1	T	1
3	TC	3

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1) FROZEN SECTION DIAGNOSIS RENAL CORTICAL NEOPLASM; MARGIN NEGATIVE. [REDACTED]
PERMANENT DIAGNOSIS: SAME

[REDACTED]

Source: NCI Genomic Data Commons file 59bfae43-2e38-406f-9f85-6181fc02d1ff (TCGA-BP-4972.A19C543C-72D9-4EA9-9F1C-CE2BCE7F51CA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).